Gene-level copy-number profile of tumor specimen C3L-06075-56 from CPTAC case C3L-06075, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 68.0 years (24,837 days).
Specimen C3L-06075-56: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f770e135-b76a-425c-a3fa-bb8ebca91738.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06075-50 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/2258aad3-b688-48d9-bef7-2c3bc4883745

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 603; copy number 2: 57,533; copy number 3: 140; copy number 4: 21; copy number 5: 17; copy number 6: 5; copy number 8: 1; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:182,588,093–182,617,810, 2 genes: AC021055.1, RPL7L1P8.
- chr5:177,992,235–177,996,242, 1 gene: PROP1.
- chr8:12,064,389–12,087,445, 2 genes: DEFB130B, RNA5SP253.
- chr9:60,914,407–61,453,030, 12 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr11:86,649–207,428, 10 genes (within-gene range 0–2): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3, AC069287.2.
- chr15:21,328,380–22,095,857, 45 genes: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.
- chr15:22,160,431–22,202,734, 5 genes: IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3.
- chr17:75,394,123–75,409,188, 3 genes (within-gene range 0–2): AC011933.3, MIR3678, RNU6-938P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene, copy number 8: RPL31P12.
- chr1:223,951,394–223,992,594, 1 gene, copy number 6 (within-gene range 2–6): GTF2IP20.
- chr1:223,992,743–224,010,612, 2 genes, copy number 6: AC138393.1, AC138393.3.
- chr6:31,528,114–31,558,829, 9 genes, copy number 5: RPL15P4, MCCD1, DDX39B, ATP6V1G2-DDX39B, SNORD117, SNORD84, DDX39B-AS1, ATP6V1G2, NFKBIL1.
- chr7:77,083,787–77,122,116, 2 genes, copy number 6 (within-gene range 2–6): FAM185BP, AC007000.1.
- chr8:12,095,176–12,099,536, 1 gene, copy number 11: DEFB108D.
- chr11:18,529,609–18,634,791, 6 genes, copy number 5: UEVLD, Metazoa_SRP, SPTY2D1OS, AC112694.1, AC112694.2, SPTY2D1.
- chr14:18,333,726–18,343,144, 2 genes, copy number 5: CR383658.1, RNU6-458P.

Autosomal genes at a single copy (total copy number 1): 600. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
